Somatic mutation profile of tumor specimen TCGA-S6-A8JY-01A (aliquot TCGA-S6-A8JY-01A-11D-A435-10) from TCGA case TCGA-S6-A8JY, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 28.0 years (10,219 days).
Specimen TCGA-S6-A8JY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98ec695c-5ca6-423c-820e-77283e284c2d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S6-A8JY-10A (Blood Derived Normal), aliquot TCGA-S6-A8JY-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c514483-d3ba-4466-a754-9b21cf12264e

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 2, Intron 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX54 | c.469C>T p.R157W | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs760920220, COSV58373329; called by muse, mutect2, varscan2
- IL17REL | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1454473833; called by muse, mutect2
- MGA | c.2755T>G p.L919V | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.381); catalogued as rs780808996; called by muse, mutect2, varscan2
- SLC12A8 | c.122C>G p.T41S | Missense Mutation (SNP) | VAF 52/213 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs762966990, COSV58866236; called by muse, mutect2, varscan2
- TLR7 | c.557G>T p.R186L | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.511); catalogued as COSV66124215; called by muse, mutect2, varscan2
- ZNF606 | c.1448C>G p.P483R | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100071785, COSV58707428; called by muse, mutect2, varscan2
- BRS3 | c.716T>G p.L239W | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FCGBP | c.8842C>A p.H2948N | Missense Mutation (SNP) | VAF 49/408 reads (12%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- HIVEP1 | c.1854_1855del p.N619* | Frame Shift Del (DEL) | VAF 23/92 reads (25%) | called by mutect2, pindel, varscan2
- PER3 | c.1435G>C p.E479Q | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- SIRT5 | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC17A4 | c.1121-1G>A p.X374_splice | Splice Site (SNP) | VAF 30/101 reads (30%) | called by muse, mutect2, varscan2
- TWNK | c.1912C>G p.L638V | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- GNL3L | c.1524C>T p.R508= | Silent (SNP) | VAF 34/106 reads (32%) | called by muse, mutect2, varscan2
- PEX19 | c.9C>A p.A3= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as rs373206658; called by muse, mutect2, varscan2
- C7orf26 | c.1149-376T>C | Intron (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- TCF3 | c.1823-485T>G | Intron (SNP) | VAF 37/138 reads (27%) | called by muse, mutect2, varscan2
